Somatic mutation profile of tumor specimen TCGA-LP-A4AU-01A (aliquot TCGA-LP-A4AU-01A-32D-A243-09) from TCGA case TCGA-LP-A4AU, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 35.8 years (13,074 days).
Specimen TCGA-LP-A4AU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad03f441-8c2e-4314-9715-9ed6334bc03b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LP-A4AU-10A (Blood Derived Normal), aliquot TCGA-LP-A4AU-10A-01D-A243-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3edf622-79d4-42a6-b31b-fddce5708d97

The open-access MAF lists 56 somatic variants for this specimen: 38 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 17, Nonsense Mutation 4, Frame Shift Del 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.8060C>T p.S2687L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs144746572, COSV57324300; ClinVar: uncertain significance; called by mutect2, varscan2
- BPIFB4 | c.1745-1G>A p.X582_splice | Splice Site (SNP) | VAF 9/66 reads (14%) | catalogued as COSV64950651; called by muse, mutect2, varscan2
- CAPN6 | c.564C>G p.D188E | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100136769; called by muse, mutect2
- CARMIL2 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs201634531, COSV58030883; called by muse, mutect2, varscan2
- CASKIN2 | c.3376C>T p.R1126C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1219094628, COSV58592919; called by muse, mutect2, varscan2
- CHERP | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.052); catalogued as COSV52222300; called by muse, mutect2, varscan2
- CNKSR2 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); catalogued as COSV54249415, COSV54250355; called by muse, mutect2, varscan2
- DBN1 | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs974680937, COSV99445718; called by muse, mutect2, varscan2
- ELAVL4 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV63914167; called by muse, mutect2, varscan2
- ESRP1 | c.913T>G p.F305V | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64407779; called by muse, mutect2
- FAM98C | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV53038106; called by muse, mutect2
- GABPB2 | c.653C>G p.S218* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as COSV64460494; called by muse, mutect2, varscan2
- GP1BA | c.968G>A p.W323* | Nonsense Mutation (SNP) | VAF 4/45 reads (9%) | catalogued as COSV99850923; called by muse, mutect2, varscan2
- HERC2 | c.5959A>C p.S1987R | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.042); catalogued as COSV55307185; called by muse, mutect2, varscan2
- ITGA10 | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as rs781987259, COSV65195979; called by muse, mutect2, varscan2
- KAT2A | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs373255391; called by muse, mutect2, varscan2
- KCTD15 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV99393080; called by muse, mutect2
- KIF16B | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100733954; called by muse, mutect2
- MACF1 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV58359132; called by muse, mutect2, varscan2
- NBEAL2 | c.7856C>T p.A2619V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs754216869, COSV52754106; called by muse, mutect2, varscan2
- NDUFAF3 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV58243902; called by muse, mutect2, varscan2
- NT5E | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.068); catalogued as COSV57627248; called by muse, mutect2, varscan2
- OFD1 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1454731121, CM130032, COSV60794234; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OSGEP | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs1256851937, COSV52833377; called by muse, mutect2
- PCDH12 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.028); catalogued as COSV51519123; called by muse, mutect2, varscan2
- PCDH19 | c.1615G>A p.G539S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55257497; called by muse, mutect2, varscan2
- RPS6KA6 | c.1958C>T p.S653L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV53116024; called by muse, mutect2, varscan2
- SESTD1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as COSV100090303; called by muse, mutect2
- SP3 | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs761430393, COSV59466068; called by muse, mutect2, varscan2
- SUSD4 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV59553027; called by muse, mutect2
- TAPBP | c.288C>G p.F96L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV69666933; called by muse, mutect2, varscan2
- TTLL13P | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs140522106; called by muse, mutect2, varscan2
- TTLL2 | c.1552C>T p.H518Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV53442523; called by muse, mutect2
- ZNF180 | c.1342C>G p.Q448E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.743); catalogued as COSV99659674; called by muse, mutect2
- ZNF536 | c.2851G>A p.G951R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1353237599, COSV62818135; called by muse, mutect2, varscan2
- ABITRAM | c.370del p.E124Kfs*33 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel
- MUC2 | c.2449G>T p.E817* | Nonsense Mutation (SNP) | VAF 9/134 reads (7%) | called by muse, mutect2
- TNFRSF25 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ASAP2 | c.2748A>C p.A916= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV99431844; called by muse, mutect2
- CPNE2 | c.1161C>T p.F387= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV99321312; called by muse, mutect2, varscan2
- CYP21A2 | c.360C>T p.H120= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV64473179; called by muse, mutect2, varscan2
- DLC1 | c.4398C>A p.S1466= (on ENST00000276297 / NM_001348081.2; = p.S1029= on NM_006094.5) | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV52290005; called by muse, mutect2, varscan2
- DYM | c.1839G>A p.A613= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs770269902, COSV53983519; called by mutect2, varscan2
- DZIP1L | c.1710C>T p.P570= | Silent (SNP) | VAF 25/172 reads (15%) | catalogued as rs1290149648, COSV59519168; called by muse, mutect2, varscan2
- GPX7 | c.297G>A p.E99= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV63652364; called by muse, mutect2, varscan2
- IL6R | c.321C>T p.H107= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV100690626; called by muse, mutect2
- MUC2 | c.879G>A p.K293= | Silent (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- NFYC | c.1323C>T p.I441= (on ENST00000308733 / NM_001308114.1; = p.I318= on NM_014223.5) | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV100438299; called by muse, mutect2
- NRXN2 | c.2400C>T p.R800= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs371387618; called by muse, mutect2, varscan2
- OR10AG1 | c.597G>A p.T199= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs750193037, COSV56631361; called by muse, mutect2, varscan2
- OR4S1 | c.105C>G p.L35= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV60678657; called by muse, mutect2, varscan2
- PCDHGB7 | c.1605C>T p.R535= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs199965876; called by muse, mutect2, varscan2
- RPL23A | c.57G>A p.A19= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV99411682; called by muse, mutect2, varscan2
- SAMD8 | c.63G>A p.L21= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV65508983; called by muse, mutect2, varscan2
- SLC44A2 | c.1467G>A p.P489= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs1212755756, COSV59839242; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826941 C>T | 3'Flank (SNP) | VAF 12/93 reads (13%) | catalogued as rs770950922; called by muse, mutect2, varscan2
